Gene-level copy-number profile of tumor specimen HTMCP-03-06-02179-01A from CGCI case HTMCP-03-06-02179, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02179-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dc1cfc46-f277-4bfe-a01f-1304d3aaf476.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02179-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/24c0442d-1ccb-4df7-b48a-904e9d536000

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 2,316; copy number 2: 10,877; copy number 3: 31,663; copy number 4: 10,432; copy number 5: 2,042; copy number 6: 323; copy number 7: 664; copy number 8: 52; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,838,125–12,841,357, 1 gene: PRAMEF30P.
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–3): PRAMEF2.
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr14:106,790,691–106,803,233, 2 genes: IGHV3-72, IGHV3-73.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:13,609,858–13,681,138, 7 genes: POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3.
- chr21:23,477,641–23,490,724, 1 gene: AP000459.1.
- chr21:44,107,373–44,210,114, 3 genes (within-gene range 0–2): PWP2, GATD3A, LINC01678.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 718 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–693,352, 27 genes, copy number 7: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1.
- chr5:850,291–45,895,970, 648 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr6:3,224,277–3,303,373, 2 genes, copy number 9 (within-gene range 3–9): TUBB2B, PSMG4.
- chr19:39,306,566–39,846,379, 41 genes, copy number 8: LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL.

Autosomal genes at a single copy (total copy number 1): 2,316. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
